Gene-level copy-number profile of tumor specimen TCGA-DM-A0XF-01A from TCGA case TCGA-DM-A0XF, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.5 years (25,032 days).
Specimen TCGA-DM-A0XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.34f02c91-ec41-4431-80f2-ed16a43c1ef5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A0XF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d384f24-b0e5-49b0-b526-a884b8e18408

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 7,822; copy number 3: 2,274; copy number 4: 41,625; copy number 5: 4,055; copy number 6: 386; copy number 7: 170; copy number 8: 2,283; copy number 10: 847; copy number 11: 346; copy number 14: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A0XF-01A-11D-A151-01): tumor purity 0.59, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,201 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:25,948,657–25,949,986, 2 genes, copy number 11: AC010719.1, MIR148A.
- chr8:99,796,615–145,066,685, 714 genes, copy number 10–14 (broad region; genes not listed).
- chr20:41,340,821–51,905,030, 279 genes, copy number 11 (broad region; genes not listed).
- chr20:57,105,741–59,259,113, 65 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr20:61,252,261–61,940,617, 1 gene, copy number 10 (within-gene range 8–10): CDH4.
- chr20:61,717,506–64,313,132, 140 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
